Gene-level copy-number profile of tumor specimen 1105201 from CPTAC case C208854, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Temporal lobe; Tumor grade: G4.
Specimen 1105201: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 31474fd3-42a2-4bd2-b35c-ad5c1e09caeb.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator 1105214 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,708 have no estimate.
https://portal.gdc.cancer.gov/files/af0d8c94-dad9-4cec-bb72-6db68cdde795

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 93; copy number 1: 5,548; copy number 2: 50,307; copy number 3: 2,769; copy number 4: 185; copy number 7: 8; copy number 8: 5.

Homozygous deletions (total copy number 0; autosomes only): 93 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–22,029,594, 8 genes (within-gene range 0–1): MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,012,536, 3 genes (within-gene range 0–1): AL449423.1, CDKN2B, UBA52P6.
- chr10:131,092,391–133,778,699, 82 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 13 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–64,116, 8 genes, copy number 7: DDX11L1, WASH7P, MIR6859-1, MIR1302-2HG, MIR1302-2, FAM138A, OR4G4P, OR4G11P.
- chr16:52,198,012–52,280,638, 3 genes, copy number 8: AC007333.2, AC007333.1, CASC22.
- chr16:52,436,772–52,437,474, 1 gene, copy number 8: AC007490.1.
- chr16:55,007,982–55,008,306, 1 gene, copy number 8: MTND5P34.

Autosomal genes at a single copy (total copy number 1): 2,692. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
